Gene-level copy-number profile of tumor specimen TCGA-67-3774-01A from TCGA case TCGA-67-3774, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.1 years (26,704 days).
Specimen TCGA-67-3774-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.5f204e58-65a1-4d9e-b9ca-777e007934af.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-67-3774-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a1276f96-d09a-431e-aa80-6ce344186164

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,158; copy number 2: 45,923; copy number 3: 2,100; copy number 4: 167; copy number 5: 187; copy number 6: 241; copy number 7: 34; copy number 8: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-67-3774-01A-01D-0944-01): tumor purity 0.48, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 471 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:16,661,766–24,562,544, 91 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr12:25,936,683–29,381,189, 70 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:57,723,761–73,208,317, 285 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr20:53,552,770–54,070,594, 9 genes, copy number 8 (within-gene range 2–8): AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1.
- chr20:55,997,357–56,555,579, 16 genes, copy number 5: CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2.

Autosomal genes at a single copy (total copy number 1): 11,158. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
